Somatic mutation profile of tumor specimen TCGA-2G-AAGT-01A (aliquot TCGA-2G-AAGT-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAGT, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 30.0 years (10,967 days).
Specimen TCGA-2G-AAGT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c183c6f-0d67-4e23-88c8-fca24c50ebb4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAGT-10A (Blood Derived Normal), aliquot TCGA-2G-AAGT-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a0d0364-80ed-4c47-8ba2-7a76d0e6cc6d

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, In Frame Del 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ILDR2 | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54828852; called by muse, mutect2, varscan2
- OBSL1 | c.5347G>A p.E1783K | Missense Mutation (SNP) | VAF 72/178 reads (40%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.997); catalogued as COSV54703033; called by muse, mutect2, varscan2
- RPLP0 | c.840_854del p.V281_T285del | In Frame Del (DEL) | VAF 60/184 reads (33%) | catalogued as rs758838738; called by mutect2, pindel, varscan2
- SLC5A4 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs555124904; called by muse, mutect2, varscan2
- TAB3 | c.1706C>T p.P569L | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55834643; called by muse, mutect2, varscan2
- AIDA | c.567_569del p.T190del | In Frame Del (DEL) | VAF 81/230 reads (35%) | called by mutect2, pindel, varscan2
- ATAD2B | c.1512T>G p.F504L | Missense Mutation (SNP) | VAF 125/406 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRIA4 | c.2045G>C p.R682T | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- HSP90AB1 | c.971_973del p.E324del | In Frame Del (DEL) | VAF 38/97 reads (39%) | called by pindel, varscan2
- MACROD2 | c.52T>G p.L18V | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PLEKHA3 | c.231_241del p.N77Kfs*17 | Frame Shift Del (DEL) | VAF 56/160 reads (35%) | called by mutect2, pindel, varscan2
- RPGRIP1 | c.3118T>C p.W1040R | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- SHOC1 | c.1985T>C p.L662S | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- TKFC | c.1070C>A p.P357H | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- TRIM44 | c.156C>A p.F52L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- HORMAD1 | c.411C>T p.N137= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as rs368484414; called by muse, mutect2, varscan2
- OR6A2 | c.615C>T p.F205= | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as rs865944663, COSV60264638; called by muse, mutect2, varscan2
- PPP1R14D | c.336G>A p.L112= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as rs929854965; called by muse, mutect2, varscan2
